Somatic mutation profile of tumor specimen ALCH-B4IS-TTP1-A (aliquot ALCH-B4IS-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4IS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.6 years (24,706 days).
Specimen ALCH-B4IS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffcb2632-d7d5-4f4b-b309-fb68a00a12fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4IS-NB2-A (Blood Derived Normal), aliquot ALCH-B4IS-NB2-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0333ccf1-1fe0-4b5b-b228-39c72a536952

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, 5'Flank 3, RNA 2, 5'UTR 2, Intron 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC8 | c.1935C>G p.I645M (on ENST00000469044 / NM_001363941.2; = p.I631M on NM_015396.6) | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV100509603; called by muse, mutect2, varscan2
- FOXRED1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 84/657 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs146661281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNAS | c.546del p.I182Mfs*3 | Frame Shift Del (DEL) | VAF 109/776 reads (14%) | catalogued as CD076802, COSV99669004; called by mutect2, pindel, varscan2
- HCAR3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977516577, COSV63673677; called by muse, mutect2, varscan2
- MYO7A | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 62/475 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs113326082, COSV68684377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEUROD6 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 38/509 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs896170005, COSV51773938; called by muse, mutect2
- NOS3 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323257260; called by muse, mutect2, varscan2
- SGO2 | c.1850A>T p.N617I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100764619; called by muse, mutect2
- YIPF3 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs761370623; called by muse, mutect2, varscan2
- ZNF318 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1385283946, COSV58935788; called by muse, mutect2
- ARHGEF12 | c.3533-1G>A p.X1178_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
- C17orf80 | c.1786G>C p.A596P | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.132); called by muse, mutect2
- COTL1 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- DSTYK | c.2362C>G p.Q788E | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.017); called by muse, mutect2
- GRIN3A | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- LAMA3 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC8C | c.94T>G p.S32A | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2
- MBNL3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAV2 | c.5969A>G p.N1990S (on ENST00000396087 / NM_001244963.2; = p.N1931S on NM_145117.5) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLA2G4A | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- PSMA2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- TRIM3 | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS51 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF283 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP6 | c.3579A>T p.G1193= | Silent (SNP) | VAF 32/470 reads (7%) | called by muse, mutect2
- MAP3K3 | c.18A>T p.A6= | Silent (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.11055C>A p.I3685= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- NEURL1 | c.1380C>G p.P460= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- OR3A2 | c.792T>C p.G264= | Silent (SNP) | VAF 10/208 reads (5%) | catalogued as rs972902120; called by muse, mutect2
- TONSL | c.4038T>C p.A1346= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as rs782676046; called by muse, mutect2
- EP300 | c.-41G>A | 5'UTR (SNP) | VAF 18/254 reads (7%) | catalogued as COSV99607669; called by muse, mutect2
- LINC01550 | chr14:97978121 G>T | 5'Flank (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- MAGEA5 | n.342T>A | RNA (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- MIR34AHG | n.1954C>G | RNA (SNP) | VAF 20/534 reads (4%) | catalogued as rs1450906688; called by muse, mutect2
- RBM12B | c.-78+362C>T | Intron (SNP) | VAF 43/142 reads (30%) | called by mutect2, varscan2
- SCRN1 | chr7:29990196 C>T | 5'Flank (SNP) | VAF 40/313 reads (13%) | catalogued as rs1266373416; called by muse, mutect2, varscan2
- SLC5A6 | c.-330G>A | 5'UTR (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- SSU72 | chr1:1575219 G>C | 5'Flank (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- ZNF812P | n.544+2377A>G | Intron (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
